Somatic mutation profile of tumor specimen MMRF_1768_1_BM_CD138pos (aliquot MMRF_1768_1_BM_CD138pos_T1_KBS5U_K11303) from MMRF case MMRF_1768, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 64.4 years (23,507 days).
Specimen MMRF_1768_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 79b91b3f-17ba-4e88-837d-40130f40110a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1768_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1768_1_PB_Whole_C2_KBS5U_K11304; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a8c1296e-9494-4007-8557-92673d40fe75

The open-access MAF lists 126 somatic variants for this specimen: 64 protein-altering or splice-affecting, 16 silent, 46 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, 3'UTR 28, Silent 16, Intron 10, Nonsense Mutation 4, 3'Flank 3, Frame Shift Del 2, RNA 2, 5'Flank 2, Splice Site 1, 5'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFF3 | c.1844G>A p.G615E | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.89); PolyPhen possibly damaging (0.642); catalogued as COSV57866286; called by muse, mutect2, varscan2
- AGRN | c.1586C>T p.A529V | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0.183); catalogued as rs752221979, COSV65068287; ClinVar: likely benign; called by muse, mutect2, varscan2
- AGRN | c.4543G>A p.G1515S | Missense Mutation (SNP) | VAF 44/80 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.392); catalogued as rs759341481; called by muse, mutect2, varscan2
- CCDC82 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.335); catalogued as COSV53592377; called by muse, mutect2, varscan2
- CNTLN | c.2564A>T p.N855I | Missense Mutation (SNP) | VAF 45/150 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); catalogued as COSV52093420; called by muse, mutect2, varscan2
- CWH43 | c.1081G>A p.G361R | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs141315226, COSV56937388, COSV99893295; called by muse, mutect2, varscan2
- FAM161B | c.1682C>T p.T561I (on ENST00000651776; = p.T498I on NM_152445.3) | Missense Mutation (SNP) | VAF 55/121 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.209); catalogued as rs1566673291; called by muse, mutect2
- H3C4 | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 160/322 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.811); catalogued as rs750273125, COSV61911699; called by muse, mutect2, varscan2
- IGHV2-70 | c.53T>G p.L18* | Nonsense Mutation (SNP) | VAF 24/24 reads (100%) | catalogued as rs546731210; called by muse, varscan2
- IGLV4-60 | c.230A>G p.Y77C | Missense Mutation (SNP) | VAF 63/65 reads (97%) | SIFT tolerated (0.15); PolyPhen benign (0.201); catalogued as rs779430407, COSV66503442; called by muse, mutect2, varscan2
- IGLV4-69 | c.175C>T p.Q59* | Nonsense Mutation (SNP) | VAF 48/75 reads (64%) | catalogued as rs529842999; called by muse, varscan2
- JCAD | c.1691G>T p.G564V | Missense Mutation (SNP) | VAF 4/71 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV64761182; called by muse, mutect2
- KLRG2 | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.015); catalogued as COSV61800456; called by muse, mutect2, varscan2
- KRT71 | c.97C>T p.R33W | Missense Mutation (SNP) | VAF 56/142 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.928); catalogued as rs550629330, COSV99921886; called by muse, mutect2, varscan2
- LRP1B | c.7015G>A p.E2339K | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV67265763; called by muse, mutect2, varscan2
- LRRC25 | c.79G>A p.V27M | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs1021988632; called by muse, mutect2, varscan2
- NAA20 | c.452A>G p.D151G | Missense Mutation (SNP) | VAF 63/122 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.54); catalogued as rs1283525810; called by muse, mutect2, varscan2
- NKTR | c.3829C>G p.L1277V | Missense Mutation (SNP) | VAF 78/240 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV51775331; called by muse, mutect2, varscan2
- NLRC5 | c.1984G>T p.E662* | Nonsense Mutation (SNP) | VAF 60/60 reads (100%) | catalogued as COSV52660194; called by muse, mutect2, varscan2
- SLC25A40 | c.913C>A p.P305T | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV56694593; called by muse, mutect2
- SLC7A4 | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs752134918, COSV60384798; called by muse, mutect2, varscan2
- SNX21 | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 67/129 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780998892; called by muse, mutect2, varscan2
- VARS2 | c.499G>A p.V167M | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as rs773735178; called by muse, mutect2, varscan2
- ANGPTL7 | c.641G>C p.R214T | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.62); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- ATAD5 | c.3365G>T p.S1122I | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.009); called by muse, mutect2
- BRCC3 | c.520C>T p.Q174* | Nonsense Mutation (SNP) | VAF 9/10 reads (90%) | called by muse, mutect2, varscan2
- CEP104 | c.1238T>C p.M413T | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- CEP290 | c.2290G>A p.D764N | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.98); PolyPhen benign (0.009); called by muse, mutect2
- CMPK2 | c.730C>A p.P244T | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- COL6A6 | c.3361G>T p.A1121S | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- CRISP2 | c.726T>G p.I242M | Missense Mutation (SNP) | VAF 120/254 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- CYLC2 | c.187G>A p.D63N | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CYLD | c.1826G>A p.C609Y | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CYP2U1 | c.298G>A p.V100I | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- EPHA7 | c.884G>T p.R295L | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- FBXO22 | c.253G>T p.V85F | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2
- GLP2R | c.616C>T p.L206F | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGHA1 | c.491_499del p.P164_G167delinsR | In Frame Del (DEL) | VAF 3/34 reads (9%) | called by mutect2, pindel*
- IGLV4-60 | c.70G>A p.V24M | Missense Mutation (SNP) | VAF 68/71 reads (96%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- IGLV4-69 | c.89C>T p.A30V | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT tolerated (0.58); PolyPhen benign (0.022); called by muse, varscan2
- IGLV4-69 | c.246C>G p.I82M | Missense Mutation (SNP) | VAF 48/66 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); called by muse, varscan2
- KIAA1671 | c.4244del p.P1415Lfs*99 | Frame Shift Del (DEL) | VAF 34/75 reads (45%) | called by mutect2, pindel, varscan2
- KPNA2 | c.571+6T>A | Splice Region (SNP) | VAF 10/178 reads (6%) | called by muse, mutect2
- MKI67 | c.4454C>G p.T1485S | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.241); called by muse, mutect2
- PCDH10 | c.758C>A p.P253H | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.215); called by muse, mutect2
- PEAK1 | c.4898C>T p.P1633L | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PLCXD1 | c.797C>T p.S266F | Missense Mutation (SNP) | VAF 21/22 reads (95%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- POLE | c.5679C>G p.S1893R | Missense Mutation (SNP) | VAF 51/170 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- PRR11 | c.926G>C p.G309A | Missense Mutation (SNP) | VAF 39/151 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PXDN | c.2566C>A p.P856T | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RBBP8 | c.1430A>T p.N477I | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2
- RIOX2 | c.533C>T p.P178L | Missense Mutation (SNP) | VAF 13/141 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SAMD9 | c.4255T>A p.L1419M | Missense Mutation (SNP) | VAF 98/204 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SLC2A7 | c.562C>T p.L188F | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.582); called by muse, mutect2, varscan2
- SP3 | c.1290T>A p.N430K | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TBR1 | c.502G>A p.G168R | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); called by muse, mutect2
- TENT5C | c.923_932del p.M308Tfs*4 | Frame Shift Del (DEL) | VAF 27/77 reads (35%) | called by mutect2, pindel, varscan2
- THUMPD3 | c.271G>A p.V91I | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- TRIM68 | c.88G>A p.D30N | Missense Mutation (SNP) | VAF 15/200 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.222); called by muse, mutect2
- TRPV1 | c.1055A>G p.Y352C | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- TSPYL2 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 46/47 reads (98%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TTN | c.161T>C p.V54A | Missense Mutation (SNP) | VAF 36/52 reads (69%) | PolyPhen benign (0.031); called by muse, mutect2, varscan2
- VPS13D | c.11371-1G>C p.X3791_splice | Splice Site (SNP) | VAF 9/140 reads (6%) | called by muse, mutect2
- ZFP91 | c.152G>C p.R51T | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); called by muse, varscan2
- AC139530.2 | c.27G>C p.L9= | Silent (SNP) | VAF 8/30 reads (27%) | called by muse, mutect2
- CROCC2 | c.2550G>A p.R850= | Silent (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- FAM149A | c.993C>T p.D331= (on ENST00000356371 / NM_001367768.2; = p.D40= on NM_015398.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 10/10 reads (100%) | catalogued as rs576988209, COSV57026223; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.115C>T p.L39= | Silent (SNP) | VAF 33/69 reads (48%) | called by muse, mutect2, varscan2
- LCN6 | c.381G>A p.G127= | Silent (SNP) | VAF 76/122 reads (62%) | called by muse, mutect2, varscan2
- LPA | c.57T>C p.P19= | Silent (SNP) | VAF 26/57 reads (46%) | called by muse, mutect2, varscan2
- NAV3 | c.4158G>A p.L1386= | Silent (SNP) | VAF 5/92 reads (5%) | called by muse, mutect2
- OTP | c.126G>T p.P42= | Silent (SNP) | VAF 12/43 reads (28%) | called by muse, mutect2, varscan2
- PFDN2 | c.189G>A p.E63= | Silent (SNP) | VAF 8/149 reads (5%) | catalogued as rs1455432412; called by muse, mutect2
- PRR5 | c.816G>A p.A272= (on ENST00000336985 / NM_181333.4; = p.A263= on NM_015366.4) | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as rs569490184; called by muse, mutect2, varscan2
- PSD3 | c.3042G>T p.S1014= (on ENST00000440756; = p.S1013= on NM_015310.4) | Silent (SNP) | VAF 37/96 reads (39%) | called by muse, mutect2, varscan2
- RGS6 | c.816C>T p.I272= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as rs777346546, COSV59583853; called by muse, mutect2, varscan2
- RRM2 | c.294G>A p.E98= | Silent (SNP) | VAF 39/95 reads (41%) | called by muse, mutect2, varscan2
- TMEFF2 | c.708G>A p.K236= | Silent (SNP) | VAF 6/40 reads (15%) | called by muse, mutect2, varscan2
- UHRF2 | c.2109T>C p.D703= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as rs529383501; called by muse, mutect2, varscan2
- ZNF444 | c.819G>A p.S273= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as rs1417439065; called by muse, mutect2, varscan2
- AC008592.1 | chr5:95859302 A>C | 5'Flank (SNP) | VAF 38/123 reads (31%) | called by muse, mutect2, varscan2
- AC108734.4 | n.1732T>G | RNA (SNP) | VAF 24/208 reads (12%) | called by muse, mutect2, varscan2
- ADAR | c.3315+63G>A | Intron (SNP) | VAF 4/67 reads (6%) | called by muse, mutect2
- AGO2 | c.1269+95G>A | Intron (SNP) | VAF 10/21 reads (48%) | catalogued as rs1431482886; called by muse, mutect2
- ANK1 | c.126+67870C>A | Intron (SNP) | VAF 8/72 reads (11%) | called by muse, mutect2, varscan2
- ARL6IP6 | c.*353A>T | 3'UTR (SNP) | VAF 9/150 reads (6%) | called by muse, mutect2
- BHMT | c.*5G>A | 3'UTR (SNP) | VAF 164/237 reads (69%) | catalogued as rs1403925736, COSV57155008, COSV99165537; called by muse, mutect2, varscan2
- CAMK4 | c.*243C>A | 3'UTR (SNP) | VAF 14/53 reads (26%) | catalogued as rs370589508; called by muse, mutect2, varscan2
- CCDC90B | chr11:83255952 T>C | 3'Flank (SNP) | VAF 17/71 reads (24%) | catalogued as rs1438247873; called by muse, mutect2, varscan2
- CDC40 | c.*1716G>C | 3'UTR (SNP) | VAF 15/66 reads (23%) | called by muse, mutect2, varscan2
- CHST10 | c.*709C>T | 3'UTR (SNP) | VAF 59/157 reads (38%) | called by muse, mutect2, varscan2
- COBLL1 | c.*1006G>C | 3'UTR (SNP) | VAF 16/42 reads (38%) | called by muse, mutect2, varscan2
- DACH2 | c.1751-1006G>T | Intron (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2, varscan2
- DCAF4L2 | c.*1864A>G | 3'UTR (SNP) | VAF 25/43 reads (58%) | called by muse, mutect2, varscan2
- DEK | c.*860C>T | 3'UTR (SNP) | VAF 12/88 reads (14%) | called by muse, mutect2, varscan2
- DHX33 | c.*1923T>C | 3'UTR (SNP) | VAF 9/19 reads (47%) | catalogued as rs1203580971; called by mutect2, varscan2
- EDIL3 | c.*1927T>C | 3'UTR (SNP) | VAF 30/96 reads (31%) | catalogued as rs1035367174; called by muse, mutect2, varscan2
- EXTL3 | c.*2200G>A | 3'UTR (SNP) | VAF 18/37 reads (49%) | catalogued as rs776715130; called by muse, mutect2, varscan2
- FAM241A | c.*1368C>A | 3'UTR (SNP) | VAF 6/73 reads (8%) | called by muse, mutect2
- FAM87A | n.2123G>A | RNA (SNP) | VAF 12/26 reads (46%) | catalogued as rs960073199; called by muse, mutect2, varscan2
- FDX1 | c.*1695T>G | 3'UTR (SNP) | VAF 25/65 reads (38%) | called by muse, mutect2, varscan2
- GNAQ | c.*1745A>T | 3'UTR (SNP) | VAF 12/47 reads (26%) | called by muse, mutect2, varscan2
- GYS2 | c.*304_*305del | 3'UTR (DEL) | VAF 20/84 reads (24%) | called by pindel, varscan2
- INSC | c.*116T>C | 3'UTR (SNP) | VAF 37/97 reads (38%) | called by muse, mutect2, varscan2
- KHDRBS1 | c.*322A>C | 3'UTR (SNP) | VAF 20/38 reads (53%) | catalogued as rs896389970; called by muse, varscan2
- LTB | c.163-111G>A | Intron (SNP) | VAF 165/321 reads (51%) | called by muse, mutect2, varscan2
- MAPT | c.*637G>A | 3'UTR (SNP) | VAF 24/67 reads (36%) | catalogued as rs1007305232; called by muse, mutect2, varscan2
- MDM2 | c.*5365_*5373del | 3'UTR (DEL) | VAF 6/32 reads (19%) | called by mutect2, varscan2
- MROH8 | chr20:37160131 G>A | 5'Flank (SNP) | VAF 61/131 reads (47%) | catalogued as rs376907846; called by muse, mutect2, varscan2
- OR2B2 | c.-60G>T | 5'UTR (SNP) | VAF 45/142 reads (32%) | called by muse, mutect2, varscan2
- PANK3 | c.*7945T>C | 3'UTR (SNP) | VAF 6/63 reads (10%) | called by muse, mutect2, varscan2
- PDE10A | c.*3689del | 3'UTR (DEL) | VAF 4/45 reads (9%) | called by mutect2, pindel
- PREX1 | c.*139G>A | 3'UTR (SNP) | VAF 13/24 reads (54%) | called by muse, mutect2
- RAD1 | chr5:34906790 C>T | 3'Flank (SNP) | VAF 35/56 reads (63%) | catalogued as rs767889459; called by muse, mutect2, varscan2
- RBM7 | c.*2607del | 3'UTR (DEL) | VAF 24/122 reads (20%) | called by mutect2, pindel, varscan2
- RNMT | c.*3141_*3152del | 3'UTR (DEL) | VAF 71/187 reads (38%) | called by mutect2, pindel, varscan2
- SLC38A5 | c.130-250C>T | Intron (SNP) | VAF 18/18 reads (100%) | catalogued as rs185696494; called by muse, mutect2, varscan2
- TECTA | chr11:121190962 C>T | 3'Flank (SNP) | VAF 20/87 reads (23%) | catalogued as rs1021887037; called by muse, mutect2, varscan2
- TMIE | c.*87G>A | 3'UTR (SNP) | VAF 19/66 reads (29%) | catalogued as rs554119481; called by muse, mutect2, varscan2
- TMPPE | c.*186C>G | 3'UTR (SNP) | VAF 17/63 reads (27%) | catalogued as rs1017608436; called by muse, mutect2, varscan2
- TP63 | c.1350-6183G>T | Intron (SNP) | VAF 128/387 reads (33%) | called by muse, varscan2
- TRIP10 | c.984+28G>A | Intron (SNP) | VAF 16/32 reads (50%) | called by muse, mutect2, varscan2
- VPS13B | c.1206+63G>A | Intron (SNP) | VAF 4/21 reads (19%) | catalogued as rs1386723417; called by muse, mutect2, varscan2
- ZBTB10 | c.*6563A>G | 3'UTR (SNP) | VAF 46/85 reads (54%) | called by muse, mutect2, varscan2
- ZNF410 | c.913+422_913+432del | Intron (DEL) | VAF 17/43 reads (40%) | called by mutect2, pindel, varscan2
- ZNF525 | c.*813G>A | 3'UTR (SNP) | VAF 19/235 reads (8%) | called by muse, mutect2
